Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A6RA, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A6RA-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -

METASTATIC CARCINOMA INVOLVING ONE (1) OF FIFTEEN (15) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN THREE (3) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE $4 + 4 = 8$ WITH TERTIARY GLEASON PATTERNS 3 AND 5.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.9 CM.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 40% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE ANTERIOR RIGHT APEX REGION (SLIDE 3M).
- F. LEFT SEMINAL VESICLE IS INVOLVED BY CARCINOMA (SLIDE 3C).
- G. THE RIGHT SEMINAL VESICLES ARE FREE OF CARCINOMA.
- H. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- I. PERINEURAL INVASION IS IDENTIFIED.
- J. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- K. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- L. PATHOLOGIC TNM STAGE: pT3b N1 MX.
- M. TNM HISTOLOGIC GRADE = G4.
- N. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 21.46
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 4
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 8
GLEASON 4/5 PERCENTAGE: 80%
WEIGHT OF PROSTATE: 67.62gm
TUMOR SIZE: Maximum dimension: 1.9 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: > 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - NOS
EXTRAPROSTATIC EXTENSION: Yes - Established (> 0.8mm)
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: Yes
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
LYMPH NODES EXAMINED: 18
LYMPH NODES POSITIVE: 1
T STAGE, PATHOLOGIC: pT3b
N STAGE, PATHOLOGIC: pN1
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

ICD-O-3

Adenocarcinoma, acinar
8140/3

Adenocarcinoma NOS
8140/3

Site Prostate NOS
C61.9

GW 8/2/13

Site:	W 7/5/13	Yes	No
MPAA Discrepancy			

Source: NCI Genomic Data Commons file 43283b86-df20-46ad-a452-959853ec5844 (TCGA-EJ-A6RA.556DE138-DE44-471D-94ED-CB755E3221C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).